MMRF case MMRF_1309 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/34c9551c-f83e-447c-877b-b101208d07b6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.7 years (30,580 days); ISS stage: II; Days to last known disease status: 1,441 days (3.9 years); Days to last follow up: 1,441 days (3.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 3 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 34 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 90 mg/dL; Immunoglobulin G 28.9 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 5.05 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 8 g/dL; Glucose 4.68 mmol/L.
- Day 53: M Protein 1.1 g/dL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 3.91 mmol/L.
- Day 244 (ECOG 0): M Protein 0.5 g/dL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 330 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.95 mmol/L.
- Day 426 (ECOG 0): M Protein 0.8 g/dL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 6.55 mmol/L.
- Day 517 (ECOG 0): M Protein 2.2 g/dL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 3.96 mmol/L.
- Day 608 (ECOG 1): Immunoglobulin G 27.4 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 8.2 g/dL; Glucose 5.67 mmol/L.
- Day 706 (ECOG 1): M Protein 2.6 g/dL; Immunoglobulin G 29.3 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 8.8 g/dL; Glucose 4.73 mmol/L.
- Day 790 (ECOG 1): M Protein 2.9 g/dL; Immunoglobulin G 34 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 9.1 g/dL; Glucose 5.56 mmol/L.
- Day 881 (ECOG 1): M Protein 2 g/dL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 8.8 g/dL; Glucose 5.39 mmol/L.
- Day 979 (ECOG 1): M Protein 2.3 g/dL; Immunoglobulin G 32.6 g/L; Beta 2 Microglobulin 0.8 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 9.1 g/dL; Glucose 5.78 mmol/L.
- Day 1,070 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69.9 mg/dL; Immunoglobulin G 34.5 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 8.6 g/dL; Glucose 7.04 mmol/L.
- Day 1,252 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 83.2 mg/dL; Immunoglobulin G 29.3 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 8.3 g/dL; Glucose 5.5 mmol/L.
- Day 1,343 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 54.8 mg/dL.
- Day 1,441 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 62.8 mg/dL; Immunoglobulin G 31.2 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 8.5 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -21: Weight: 100 kg; Height: 157 cm.

Biospecimens (3 samples)
- Sample MMRF_1309_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_1309_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
- Sample MMRF_1309_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 979 days (2.7 years).
